Gene-level copy-number profile of tumor specimen TCGA-BA-A4IH-01A from TCGA case TCGA-BA-A4IH, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Basaloid squamous cell carcinoma; Tissue or organ of origin: Oropharynx, NOS; Tumor grade: G3; Age at diagnosis: 57.8 years (21,094 days).
Specimen TCGA-BA-A4IH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.3450eaec-f440-4d70-8ae7-90dfd72cda70.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BA-A4IH-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d18a6b9b-600b-47fe-8a42-9283e92efd02

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 68; copy number 2: 12,883; copy number 3: 2,034; copy number 4: 41,541; copy number 5: 1,024; copy number 6: 723; copy number 7: 63; copy number 9: 1,482; copy number 11: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BA-A4IH-01A-11D-A25X-01): tumor purity 0.88, ploidy 1.87, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 68 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:85,683,848–88,524,054, 64 genes (broad region; genes not listed).
- chr11:88,612,805–88,612,911, 1 gene: RNU6-16P.
- chr14:102,770,040–102,911,500, 3 genes (within-gene range 0–2): AL132801.1, TRAF3, RNU6-1316P.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,484 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:116,921,328–198,222,513, 1,482 genes, copy number 9 (broad region; genes not listed).
- chr9:99,906,654–99,974,534, 2 genes, copy number 11 (within-gene range 2–11): STX17, AL358937.1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
